Gene-level copy-number profile of specimen HCM-SANG-1085-C20-85A-01D-A80T-32 from HCMI case HCM-SANG-1085-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Rectum, NOS; Tumor grade: G3.
Specimen HCM-SANG-1085-C20-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 34c23aa6-2902-4171-9ca8-524e32b335ad.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1085-C20-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/2ec4f4e6-2f29-4bde-842a-d52207854904

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 14,334; copy number 2: 38,709; copy number 3: 5,633; copy number 4: 175; copy number 5: 17; copy number 6: 2; copy number 7: 5; copy number 8: 3; copy number 9: 26.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,502,145–49,589,529, 11 genes: ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 53 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:50,396,192–50,934,521, 8 genes, copy number 5–8: EMB, AC112187.2, AC112187.1, AC112187.3, PARP8, AC022441.1, AC022441.3, AC022441.2.
- chr10:71,212,570–71,302,864, 1 gene, copy number 6 (within-gene range 2–6): UNC5B.
- chr10:86,435,256–86,932,825, 9 genes, copy number 5 (within-gene range 1–5): WAPL, RNU6-780P, AL731569.1, RPL7AP8, OPN4, LDB3, AC067750.1, BMPR1A, RPAP2P1.
- chr10:90,402,521–92,030,325, 27 genes, copy number 6–9: LINC02653, AL391704.1, AL391704.2, HTR7, RPP30, Y_RNA, ANKRD1, RNU6-740P, AL365434.1, AL365434.2, LINC00502, DDX18P6, NUDT9P1, PCGF5, HECTD2, AL161798.1, RPS27P1, PPP1R3C, GAPDHP28, FAF2P1, TNKS2-AS1, TNKS2, SRP9P1, AL359198.2, FGFBP3, AL359198.1, BTAF1.
- chr10:92,451,684–92,655,395, 3 genes, copy number 5: IDE, KIF11, RPL11P4.
- chr16:90,102,271–90,178,344, 1 gene, copy number 7 (within-gene range 2–7): FAM157C.
- chr16:90,110,574–90,222,851, 4 genes, copy number 7: AC133919.2, RNU6-355P, LINC02193, CICP25.

Autosomal genes at a single copy (total copy number 1): 11,478. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
